Gene-level copy-number profile of tumor specimen AP-D9X4-MU from APOLLO case AP-D9X4, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-D9X4-MU: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1ce02c9d-eadf-40e4-bd02-3625a63e9a18.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-D9X4-RY (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/de3c796f-101f-4cc2-b0c6-930b4e748525

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 7,201; copy number 2: 33,734; copy number 3: 14,272; copy number 4: 2,792; copy number 5: 23; copy number 6: 5; copy number 7: 127; copy number 9: 59; copy number 10: 6; copy number 11: 6; copy number 12: 7; copy number 14: 29; copy number 16: 11; copy number 18: 5; copy number 19: 14; copy number 20: 25; copy number 22: 26; copy number 23: 2; copy number 24: 2; copy number 25: 24; copy number 26: 8.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–36,081, 6 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A.
- chr1:89,295–133,723, 2 genes (within-gene range 0–3): AL627309.1, AL627309.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 379 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,345,099, 48 genes, copy number 22–25: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L.
- chr5:1,544,107–8,620,310, 113 genes, copy number 7–26 (broad region; genes not listed).
- chr5:9,001,774–10,777,062, 55 genes, copy number 5–14: AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1.
- chr5:12,297,399–16,192,709, 41 genes, copy number 9–26: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6.
- chr5:21,196,720–23,329,892, 19 genes, copy number 5–6: AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1.
- chr5:23,456,468–23,456,850, 1 gene, copy number 6: AC109445.1.
- chr5:24,881,943–24,910,695, 2 genes, copy number 10: AC106821.1, Y_RNA.
- chr5:26,382,519–26,749,997, 6 genes, copy number 9: AC025475.1, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1.
- chr5:34,998,101–41,071,342, 94 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,772. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
